Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A3I4, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A3I4-01A (Primary Tumor).

[page 1 of 2]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

LAB:

Phone:

Fax:

Final Report

Reviewer Initials	Reviewed: 12/21/11	

DIAGNOSIS

A) THYROID, RIGHT, EXCISION:

1. Papillary thyroid carcinoma
2. Margins are free of malignancy
3. Background lymphocytic thyroiditis
4. One benign parathyroid
5. Please see below thyroid staging parameters

B) THYROID, LEFT, EXCISION:

1. Colloid nodule
2. Background lymphocytic thyroiditis
3. No evidence of atypia or malignancy
4. One benign lymph node

*** THYROID CANCER STAGING PARAMETERS ***

Final TNM: pT2N0M0
2010 stage: I

MACROSCOPIC

SPECIMEN TYPE

Total thyroidectomy

DOMINANT TUMOR LOCATION AND SIZE

Location: Right lobe

Greatest dimension: 4.0 cm

TUMOR FOCALITY

Unifocal

MICROSCOPIC

HISTOLOGIC TYPE

Papillary carcinoma, usual type

MARGINS

Uninvolved by invasive carcinoma

LYMPHATIC VASCULAR INVASION

Present

Extent: Focal

EXTRATHYROIDAL EXTENSION

Not identified

PATHOLOGIC STAGING

EXTENT OF INVASION

pT2. (Tumor more than 2 cm but not more than 4 cm,
limited to the thyroid)

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

100-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

hw
12/21/11

[page 2 of 2]
[REDACTED]

Total nodes: 1 (adjacent to left thyroid)
Total positive nodes: 0
DISTANT METASTASIS
pM0. (Not applicable)
MACIS SCORE
4.3
PATHOLOGIC STAGE Summary
Final TNM: pT2N0M0
2010 stage: I
** The pathologic stage presumes no distant metastasis.

[REDACTED] t: [REDACTED]
Hospital Pathology Associates,

CLINICAL INFORMATION
Not listed

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Right thyroid lobe
Labeled "right thyroid lobe" and consists of a 16.2 gm, 4.2 x 4 x 2.4 cm thyroid lobe. The capsular surface is intact. The area of the isthmus is inked orange and the remainder of the capsule is inked black. The specimen is sectioned revealing a 3.8 x 4 x 2.4 cm tan-yellow soft granular mass in a superior and mid portion of the specimen. It extends to multiple capsular surfaces but does not grossly extend through it. A normal portion of parenchyma is found at the area of the isthmus and inferior aspect of the thyroid. A touch prep and frozen section are prepared.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION AND CYTOLOGIC PREPARATION: "Papillary carcinoma" is rendered [REDACTED]

The remainder of the tissue is sequentially submitted from superior to inferior in cassettes 2-12.

This case is accessioned in

Note: Tissue is taken for possible ancillary studies.

[REDACTED]

B) SOURCE: Left thyroid lobe and isthmus
Labeled "left thyroid lobe and isthmus" consists of a ragged irregular 5 gram, 3.6 x 2.6 x 1.8 cm portion of thyroid lobe and apparent isthmus. The capsular surface is ragged. The area of the isthmus is inked yellow and the remainder of the capsule is inked black. The specimen is sectioned revealing a 0.8 x 0.7 x 0.7 cm soft tan nodule in the upper pole of the specimen. It is within 0.1 cm of the black capsular surface. It does not extend through the capsule grossly. The specimen is entirely submitted from superior to inferior in five cassettes with lesion in cassettes 2-3.

[REDACTED]

MICROSCOPIC

A,B) The microscopic appearance substantiates the diagnosis. Dictation by: [REDACTED]

Interpreted at

COLLECTED: ACCESSIONED: SIGNED:

[REDACTED]

Source: NCI Genomic Data Commons file 89d79554-b96b-48de-9da9-85669d62f306 (TCGA-FY-A3I4.9D03B6BA-32C0-47A1-B296-A7E9BD2B2EEF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).